Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2GC, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2GC-06A (Metastatic).

[page 1 of 3]
DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY SUPPLEMENTARY REPORT

SUPPLEMENTARY REPORT

2. "RIGHT NECK DISSECTION LEVEL 1B": The tumour is positive with S-100, HMB-45 and Melan A consistent with melanoma.

SUPPLEMENTARY SUMMARY

1. Right neck lymph node dissection level 1A - No evidence of metastatic melanoma seen /
2. Right neck lymph node dissection level 1B - Metastatic melanoma in 1 of 6 lymph nodes; /
3. Right neck lymph node dissection level 2A - No evidence of metastatic melanoma seen /
4. Right neck lymph node dissection level 2B - No evidence of metastatic melanoma seen /
5. Right neck lymph node dissection level 3 - No evidence of metastatic melanoma seen /
6. Right neck lymph node dissection level 4 - No evidence of metastatic melanoma seen.

REPORTED BY: D:

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, submandibular
6/10/11
e 77.0

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Previous 2mm melanoma nasal tip Now right submandibular metastases. Right neck dissection. Levels IA. IB (fresh for Tumour Banking). IIA. IIB. III. IV. Histopathology. Tissue received fresh for tumour banking and tissue taken for tumour banking.

MACROSCOPIC DESCRIPTION

(Dr

Six specimens were received.

1. "RIGHT NECK DISSECTION LEVEL 1A". Fibrofatty tissue 50 x 35 x 15mm.
- A. Two lymph nodes.
- B. Four lymph nodes.
- C. Two lymph nodes.
2. "RIGHT NECK DISSECTION LEVEL 1B". Fibrofatty tissue 60 x 50 x 35mm. A submandibular gland is present 45 x 30 x 20mm. The cut surfaces of the submandibular gland is unremarkable.
- A-B. One ?involved lymph node (15 x 15 x 13mm) trisected. (A portion of this lymph node has been taken for Tumour Banking).
- C. Three lymph nodes.
- D. Two lymph nodes.
- E. Representative sections of submandibular gland.

[page 2 of 3]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

3. "RIGHT NECK DISSECTION LEVEL 2A". Fibrofatty tissue 60 x 40 x 20mm.

- A. One bisected lymph node
- B. Four lymph nodes.
- C. One lymph node

4. "RIGHT NECK DISSECTION LEVEL 2B". Fibrofatty tissue 50mm x 45 x 15mm.

- A. One bisected lymph node.
- B. One bisected lymph node.
- C. Three lymph nodes.
- D. Four lymph nodes.

5. "RIGHT NECK DISSECTION LEVEL 3". Fibrofatty tissue 55 x 40 x 25mm.

- A-B. One bisected lymph node in each block.
- C. Three lymph nodes.
- D. One bisected lymph node.
- E. Four lymph nodes.

6. "RIGHT NECK DISSECTION LEVEL 4". Fibrofatty tissue 50mm in maximum dimension.

- A. Five lymph nodes.
- B. Two lymph nodes.

MICROSCOPIC REPORT

1. "RIGHT NECK DISSECTION LEVEL 1A": The sections show 3 lymph nodes with no evidence of metastatic melanoma seen.

2. "RIGHT NECK DISSECTION LEVEL 1B": The sections show metastatic tumour in 1 of 6 lymph nodes. The involved node is the node seen macroscopically and sampled for tumour banking. It is partially effaced by a spindled tumour consistent with metastatic melanoma. **Confirmatory immunostains are in progress and a supplementary report will be issued.** The melanoma involves about 70% of the node sampled with parenchymal distribution. No definite extranodal spread is seen. Serous salivary gland is present in block 2E.

3. "RIGHT NECK DISSECTION LEVEL 2A": The sections show 4 lymph nodes with no evidence of metastatic melanoma seen. Serous salivary gland is present in block 3A.

4. "RIGHT NECK DISSECTION LEVEL 2B": The sections show 9 lymph nodes with no evidence of metastatic melanoma seen.

5. "RIGHT NECK DISSECTION LEVEL 3": The sections show 8 lymph nodes with no evidence of metastatic melanoma seen.

6. "RIGHT NECK DISSECTION LEVEL 4": The sections show 4 lymph nodes with no evidence of metastatic melanoma seen.

COMMENT

Many lymph nodes contain scattered aggregates of melanophages.

SUMMARY

1. Right neck lymph node dissection level 1A - No evidence of metastatic melanoma seen
/

2. Right neck lymph node dissection level 1B - Consistent with metastatic melanoma in 1 of 6 lymph nodes;
confirmatory immunostains in progress

[page 3 of 3]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

- /
3. Right neck lymph node dissection level 2A - No evidence of metastatic melanoma seen
- /
4. Right neck lymph node dissection level 2B - No evidence of metastatic melanoma seen
- /
5. Right neck lymph node dissection level 3 - No evidence of metastatic melanoma seen
- /
6. Right neck lymph node dissection level 4 - No evidence of metastatic melanoma seen.

REPORTED BY: Dr

Source: NCI Genomic Data Commons file 777c52b2-332d-4a53-ae5b-b40d7d445978 (TCGA-EE-A2GC.F2DE0CF5-7EE7-430E-AB09-BF8487D27A0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).